Somatic mutation profile of tumor specimen TCGA-AA-3561-01A (aliquot TCGA-AA-3561-01A-01D-1953-10) from TCGA case TCGA-AA-3561, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.3 years (26,420 days).
Specimen TCGA-AA-3561-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43fdaebf-4906-4009-9933-cb70a5cef01f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3561-10A (Blood Derived Normal), aliquot TCGA-AA-3561-10A-01W-0831-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a49af316-90e1-469f-ae97-fcde40def647

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 14, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNG8 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV99554948; called by muse, varscan2
- CBLN2 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as rs1392007698, COSV54051150; called by muse, mutect2, varscan2
- CNTLN | c.3384C>A p.H1128Q | Missense Mutation (SNP) | VAF 86/207 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as COSV99263761; called by muse, mutect2, varscan2
- FOXG1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57395156; called by muse, mutect2, varscan2
- GPR26 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.056); catalogued as rs1174980270, COSV52933378; called by muse, mutect2, varscan2
- HECW1 | c.2057C>T p.S686L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as rs769914359, COSV67834855; called by muse, mutect2, varscan2
- LPAR5 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.451); catalogued as rs754791280, COSV100320982; called by muse, mutect2, varscan2
- MDGA2 | c.2140C>T p.Q714* (on ENST00000399232 / NM_001113498.2; = p.Q416* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 134/176 reads (76%) | catalogued as COSV100636850; called by muse, mutect2, varscan2
- NAV3 | c.4981G>A p.D1661N | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV99889529; called by muse, mutect2, varscan2
- PRDM16 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1060501005, COSV99576275; ClinVar: uncertain significance; called by muse, mutect2
- RIMS2 | c.2642G>A p.R881Q (on ENST00000666250 / NM_001348490.2; = p.R689Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376486274, COSV99171565; called by muse, mutect2, varscan2
- SIGLEC6 | c.1187G>C p.R396T | Missense Mutation (SNP) | VAF 244/569 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as COSV100585298, COSV100585648, COSV58434424; called by muse, mutect2, varscan2
- TEPSIN | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs541063582, COSV56142852; called by muse, mutect2, varscan2
- TRIM65 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs200296747; called by muse, mutect2, varscan2
- TRPS1 | c.500C>A p.A167E (on ENST00000220888 / NM_001330599.2; = p.A180E on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/202 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.107); catalogued as COSV55229868; called by muse, mutect2, varscan2
- MYH15 | c.450C>T p.P150= | Silent (SNP) | VAF 166/444 reads (37%) | catalogued as rs368538929; called by muse, mutect2, varscan2
- ZNF418 | c.1815G>A p.A605= | Silent (SNP) | VAF 98/226 reads (43%) | catalogued as rs746811618, COSV68675842; called by muse, mutect2, varscan2
